Gene-level copy-number profile of tumor specimen MP2PRT-PARVJJ-TBP1-A from MP2PRT case MP2PRT-PARVJJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,151 days).
Specimen MP2PRT-PARVJJ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ebc0cc81-51eb-4713-982c-07b497adebe3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARVJJ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/f9b99d93-4639-4d1e-895f-1cb4363ad78d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 5,569; copy number 2: 53,251.

Homozygous deletions (total copy number 0; autosomes only): 91 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,349,835–21,638,676, 16 genes: IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–1): PRB1.
- chr12:45,874,035–45,882,266, 2 genes (within-gene range 0–1): RN7SL246P, KNOP1P2.
- chr14:105,851,705–106,122,709, 62 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.
- chr22:22,834,865–22,886,379, 9 genes (within-gene range 0–1): AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,713. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
